Somatic mutation profile of tumor specimen MP2PRT-PATHUJ-TMP1-A (aliquot MP2PRT-PATHUJ-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATHUJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,435 days).
Specimen MP2PRT-PATHUJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54633fb4-ac15-4049-8f43-56e0c57db6cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHUJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHUJ-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6e86bc4-77f4-4e1e-9679-4c67cd720fe5

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH18A1 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100973122; called by muse, mutect2, varscan2
- MARCHF7 | c.473T>C p.M158T | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs746455906; called by muse, mutect2, varscan2
- PAFAH2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 114/321 reads (36%) | catalogued as COSV65339393; called by muse, mutect2, varscan2
- PAX6 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 38/277 reads (14%) | catalogued as COSV99570506; called by muse, mutect2, varscan2
- SLC22A12 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 155/461 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773677616, CM042475, COSV100327840; called by muse, mutect2, varscan2
- TTPA | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 92/536 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as rs1457023498; called by muse, mutect2, varscan2
- U2AF2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 25/425 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58272683; called by muse, mutect2
- ZNF600 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV57741934; called by muse, mutect2, varscan2
- DOCK3 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.515); called by muse, mutect2
- IFRD1 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGI2 | c.2014G>A p.G672R | Missense Mutation (SNP) | VAF 55/464 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPP7 | c.288G>C p.L96F | Missense Mutation (SNP) | VAF 11/348 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.226); called by muse, mutect2
- TMTC2 | c.1922C>G p.A641G | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TRIM52 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 53/403 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRIM58 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 37/580 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.169); called by muse, mutect2
- CDSN | c.552C>T p.R184= | Silent (SNP) | VAF 56/732 reads (8%) | catalogued as rs772728479; called by muse, mutect2
- IRF6 | c.888C>T p.D296= | Silent (SNP) | VAF 166/478 reads (35%) | catalogued as rs748882482, CX022603, COSV65418841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4D11 | c.906G>A p.K302= | Silent (SNP) | VAF 25/241 reads (10%) | catalogued as COSV57585725, COSV57585770; called by muse, mutect2, varscan2
